Gene-level copy-number profile of tumor specimen C3L-04084-04 from CPTAC case C3L-04084, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.7 years (23,267 days).
Specimen C3L-04084-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 317ed027-6783-4348-b00e-5fbbe9eb89b9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04084-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/03c6fada-2816-43a5-86e7-85a1817d245b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 15; copy number 2: 3,810; copy number 3: 86; copy number 4: 47,266; copy number 5: 343; copy number 6: 6,721; copy number 7: 62; copy number 8: 14; copy number 10: 22; copy number 25: 2; copy number 59: 6; copy number 62: 24; copy number 63: 1; copy number 113: 6.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:11,618,496–12,058,227, 2 genes: AL592227.1, AL353595.1.
- chr9:21,201,469–21,240,005, 7 genes: IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14.
- chr9:21,304,326–21,351,378, 4 genes: IFNA5, IFNA20P, KLHL9, IFNA6.
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–4): CDKN2A-DT.
- chr9:23,500,691–24,592,104, 10 genes: AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1.
- chr10:38,601,418–38,605,609, 1 gene: ABCD1P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 61 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:41,506,365–42,035,925, 1 gene, copy number 10 (within-gene range 4–10): HIVEP3.
- chr1:41,585,306–42,703,805, 21 genes, copy number 10: AC119676.1, AL158216.1, HNRNPFP1, AC114492.1, GUCA2B, GUCA2A, FOXJ3, AC096540.1, RIMKLA, AL513331.1, ZMYND12, PPCS, CCDC30, RPS3AP11, TMSB4XP1, RNU6-536P, AL445669.1, PPIH, AC098484.4, AC098484.2, YBX1.
- chr7:54,759,348–55,878,164, 31 genes, copy number 62–113 (within-gene range 7–113): SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2.
- chr7:56,288,230–56,365,270, 6 genes, copy number 59: AC073136.1, AC073136.2, AC093392.1, RNU6-1335P, SEPTIN14P24, CICP8.
- chr7:65,773,620–65,814,775, 2 genes, copy number 25: GTF2IP5, RNU6-912P.

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
